Gene-level copy-number profile of tumor specimen ALCH-AFEU-TTP1-A from ALCHEMIST case ALCH-AFEU, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 55.3 years (20,191 days).
Specimen ALCH-AFEU-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 2ea1c427-2d88-4227-9f0a-862f881159c3.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AFEU-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,225 have no estimate.
https://portal.gdc.cancer.gov/files/2329e7a9-4b63-40dd-9749-ab12c5063443

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 12; copy number 1: 3,092; copy number 2: 51,516; copy number 3: 3,678; copy number 4: 90; copy number 5: 8; copy number 6: 2.

Homozygous deletions (total copy number 0; autosomes only): 12 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:238,152,889–238,168,900, 2 genes (within-gene range 0–2): KLHL30-AS1, ERFE.
- chr4:1,009,936–1,028,972, 2 genes: FGFRL1, AC019103.1.
- chr6:170,254,334–170,279,887, 3 genes: AL109910.1, AL109910.2, LINC01624.
- chr7:98,214,624–98,252,232, 1 gene: TECPR1.
- chr9:136,542,881–136,543,835, 1 gene (within-gene range 0–1): AL592301.1.
- chr14:104,138,723–104,180,894, 1 gene: KIF26A.
- chr16:668,105–674,174, 1 gene (within-gene range 0–1): RHOT2.
- chr19:956,485–958,149, 1 gene (within-gene range 0–2): AC005391.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 10 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:61,190,003–61,453,030, 7 genes, copy number 5: SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P.
- chr10:37,297,398–37,303,109, 2 genes, copy number 6 (within-gene range 3–6): RN7SL314P, Y_RNA.
- chr10:38,783,004–38,783,108, 1 gene, copy number 5: AL590623.1.

Autosomal genes at a single copy (total copy number 1): 3,088. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
